Somatic mutation profile of tumor specimen HCM-CSHL-0155-C50-86A (aliquot HCM-CSHL-0155-C50-86A-01D-A937-36) from HCMI case HCM-CSHL-0155-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 49.0 years (17,880 days).
Specimen HCM-CSHL-0155-C50-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8823491-fb94-4783-a703-8a1d518efff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0155-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0155-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad5e6386-97ab-428d-8983-d8c018b3842a

The open-access MAF lists 293 somatic variants for this specimen: 207 protein-altering or splice-affecting, 74 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 74, Nonsense Mutation 16, Splice Site 5, Intron 5, RNA 3, Frame Shift Del 3, In Frame Del 2, 3'UTR 2, Frame Shift Ins 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.1464G>A p.W488* | Nonsense Mutation (SNP) | VAF 81/233 reads (35%) | catalogued as rs1447749222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 80/278 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 84/324 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 86/86 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- AKR7A3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 156/244 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs756610725, COSV64389201; called by muse, mutect2, varscan2
- AMER1 | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 150/745 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143958560, COSV57668565; ClinVar: benign; called by muse, mutect2, varscan2
- AP000721.1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 121/411 reads (29%) | PolyPhen possibly damaging (0.856); catalogued as rs1359236732; called by muse, mutect2, varscan2
- ARHGAP9 | c.1609+1G>T p.X537_splice (on ENST00000393797 / NM_001319850.2; = p.X518_splice on NM_032496.4) | Splice Site (SNP) | VAF 134/222 reads (60%) | catalogued as rs1484949856; called by muse, mutect2, varscan2
- BRIP1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as CM1512696, COSV51994417; called by muse, mutect2, varscan2
- BTBD3 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656041; called by muse, mutect2, varscan2
- C8orf82 | c.650G>C p.*217Sext*151 | Nonstop Mutation (SNP) | VAF 102/1092 reads (9%) | catalogued as rs1403442286; called by muse, mutect2
- CNTN5 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 108/347 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as COSV99677387, COSV99679149; called by muse, mutect2, varscan2
- CRACD | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 154/607 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51715745; called by muse, mutect2, varscan2
- DCANP1 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs745525886; called by muse, mutect2, varscan2
- DCST1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 142/590 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.433); catalogued as rs760441746, COSV55051025; called by muse, mutect2, varscan2
- DHRS2 | c.543G>A p.A181= | Splice Region (SNP) | VAF 234/235 reads (100%) | catalogued as rs765882203, COSV51633303, COSV99161316; called by muse, mutect2, varscan2
- DNAH10 | c.488T>C p.F163S (on ENST00000409039; = p.F102S on NM_207437.3) | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68987616; called by muse, mutect2, varscan2
- DNAJC9 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 138/613 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as rs1356780140; called by muse, mutect2, varscan2
- EPB41 | c.2416-1G>C p.X806_splice (on ENST00000343067 / NM_001166005.2; = p.X530_splice on NM_004437.4) | Splice Site (SNP) | VAF 128/216 reads (59%) | catalogued as COSV58040877; called by muse, mutect2, varscan2
- ERBB2 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 536/9214 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759579850; called by muse, mutect2
- FAM135B | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 134/266 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV52702447; called by mutect2, varscan2
- FAT1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 178/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556690116; called by muse, mutect2, varscan2
- FZD2 | c.1653C>G p.F551L | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as COSV59530207; called by muse, mutect2, varscan2
- G6PD | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 224/468 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100855113; called by mutect2, varscan2
- GALNT13 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs150203694; called by muse, mutect2, varscan2
- GAS6 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781147555, COSV59849567; called by muse, mutect2, varscan2
- GDF6 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 124/817 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs1447166633, COSV54626185; called by muse, varscan2
- GLMP | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 135/630 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1223559820, COSV55295018; called by muse, mutect2, varscan2
- GLUD2 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 149/606 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100046567, COSV60151969; called by muse, mutect2, varscan2
- H3C2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 102/324 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV52518439, COSV52519759; called by muse, varscan2
- IGFLR1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 136/459 reads (30%) | catalogued as rs1005277772; called by muse, mutect2, varscan2
- IQCD | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 119/404 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1314142566; called by muse, mutect2, varscan2
- IQCE | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 306/410 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1349745353; called by muse, mutect2, varscan2
- MAML1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 128/330 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs770524065; called by muse, mutect2, varscan2
- MARS2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1039051691; called by muse, mutect2, varscan2
- MCC | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56728153; called by muse, mutect2, varscan2
- MTARC1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.802); catalogued as rs775260812; called by muse, mutect2, varscan2
- MUC17 | c.3061A>G p.S1021G | Missense Mutation (SNP) | VAF 354/355 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV100072884; called by muse, mutect2, varscan2
- MUC4 | c.7444C>G p.L2482V | Missense Mutation (SNP) | VAF 148/2130 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.374); catalogued as COSV100640295, COSV100640520; called by muse, mutect2
- NAB1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 91/405 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1053176, COSV61609598; called by muse, mutect2, varscan2
- NEB | c.13489G>C p.E4497Q | Missense Mutation (SNP) | VAF 170/268 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51449521; called by muse, mutect2, varscan2
- NPRL2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs1453959857; called by muse, mutect2, varscan2
- NR3C2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100679295; called by muse, mutect2, varscan2
- NR4A2 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59892963; called by muse, mutect2, varscan2
- NTSR2 | c.488C>G p.S163W | Missense Mutation (SNP) | VAF 170/811 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV60991230; called by muse, mutect2, varscan2
- OTOF | c.4297C>T p.R1433W (on ENST00000272371 / NM_194248.3; = p.R666W on NM_004802.4) | Missense Mutation (SNP) | VAF 263/557 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769051185, COSV99718472; called by muse, mutect2, varscan2
- PCDH1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 140/584 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1223161926; called by muse, mutect2, varscan2
- PGAP1 | c.2565G>C p.L855F | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.67); catalogued as COSV61328765; called by muse, mutect2, varscan2
- PKDCC | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 165/711 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs766142478, COSV99684802; called by muse, mutect2, varscan2
- PPM1E | c.1494T>G p.S498R | Missense Mutation (SNP) | VAF 120/599 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV57574986; called by muse, mutect2, varscan2
- PRICKLE3 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 175/180 reads (97%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs782354019; called by muse, mutect2, varscan2
- PRR22 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs751915954; called by muse, mutect2, varscan2
- PXDN | c.3790C>T p.Q1264* | Nonsense Mutation (SNP) | VAF 92/409 reads (22%) | catalogued as COSV53234653; called by muse, mutect2, varscan2
- RBMXL3 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 183/788 reads (23%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs782358096; called by muse, mutect2, varscan2
- RFC3 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 120/224 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1426651599; called by muse, mutect2, varscan2
- RHPN1 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368945775; called by muse, mutect2, varscan2
- RUBCN | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 106/696 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754358548, COSV56364971; called by muse, mutect2, varscan2
- SAMD14 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 186/726 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53309210; called by muse, mutect2, varscan2
- SCAF1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 166/641 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.723); catalogued as COSV100862143; called by muse, varscan2
- SCARB2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 96/394 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs1316817158; called by muse, mutect2, varscan2
- SEL1L2 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770442031, COSV53157989; called by muse, mutect2, varscan2
- SHROOM3 | c.5695G>T p.D1899Y | Missense Mutation (SNP) | VAF 197/421 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56029428; called by muse, mutect2, varscan2
- SIRT1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 119/663 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as rs778261267; called by muse, mutect2, varscan2
- SLC15A3 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 253/407 reads (62%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs779627240; called by muse, mutect2, varscan2
- SLC35A1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as rs141689740; called by muse, mutect2, varscan2
- SPANXN2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 186/817 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs1390452648, COSV65128478; called by muse, mutect2, varscan2
- STEAP4 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777525378; called by muse, mutect2, varscan2
- STK3 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 291/1211 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1262074313; called by muse, mutect2, varscan2
- SUN1 | c.1166G>A p.G389D (on ENST00000405266 / NM_001367651.1; = p.G269D on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 160/295 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1020606766, COSV100568677; called by muse, mutect2, varscan2
- TEDC2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 166/640 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs752195413, COSV62523034; called by muse, mutect2, varscan2
- TIMM8B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1352755224, COSV54777145; called by muse, mutect2, varscan2
- TRIM68 | c.1080G>T p.W360C | Missense Mutation (SNP) | VAF 178/342 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216932015; called by muse, mutect2, varscan2
- TTC22 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 202/552 reads (37%) | catalogued as COSV64882047; called by muse, mutect2, varscan2
- TTN | c.11482G>C p.E3828Q (on ENST00000591111; = p.E3782Q on NM_003319.4) | Missense Mutation (SNP) | VAF 232/361 reads (64%) | catalogued as COSV100592054; called by muse, mutect2, varscan2
- TTN | c.9640G>A p.D3214N (on ENST00000591111; = p.D3168N on NM_003319.4) | Missense Mutation (SNP) | VAF 189/277 reads (68%) | PolyPhen probably damaging (0.998); catalogued as rs778326573, COSV60237511; called by muse, mutect2, varscan2
- UNC13A | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as rs1332635668; called by muse, mutect2, varscan2
- USP54 | c.3134C>T p.S1045F | Missense Mutation (SNP) | VAF 132/523 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as COSV60444498; called by muse, mutect2, varscan2
- VPS13B | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 76/429 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.443); catalogued as COSV62017008; called by muse, mutect2, varscan2
- VWDE | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 264/352 reads (75%) | catalogued as COSV51735294; called by muse, mutect2
- WDR12 | c.655+1G>A p.X219_splice | Splice Site (SNP) | VAF 59/202 reads (29%) | catalogued as rs1384232411; called by muse, mutect2, varscan2
- YME1L1 | c.674T>C p.L225S (on ENST00000326799 / NM_139312.3; = p.L168S on NM_014263.4) | Missense Mutation (SNP) | VAF 233/467 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1290442325; called by muse, mutect2, varscan2
- ZNF436 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs936099841; called by muse, mutect2, varscan2
- ZNF580 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 165/660 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1397268412, COSV54401240; called by muse, mutect2, varscan2
- ZNF761 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 195/386 reads (51%) | catalogued as COSV61888244; called by muse, mutect2, varscan2
- ABCC2 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- ACAA2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 124/242 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ACP2 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 216/576 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACVR1 | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 66/232 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.2229G>C p.Q743H | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADAP1 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- AFDN | c.4478G>C p.R1493T | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AL121899.2 | c.1246dup p.R416Pfs*51 | Frame Shift Ins (INS) | VAF 90/342 reads (26%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.2300del p.R767Lfs*243 | Frame Shift Del (DEL) | VAF 187/483 reads (39%) | called by mutect2, pindel, varscan2
- APOBEC3C | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ART3 | c.1045C>T p.P349S (on ENST00000355810 / NM_001377173.1; = p.P338S on NM_001179.6) | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ATP8A2 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- B3GNT2 | c.856_858del p.K286del | In Frame Del (DEL) | VAF 151/400 reads (38%) | called by pindel, varscan2
- BCO1 | c.1325C>A p.T442K | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BLM | c.3914G>C p.R1305T | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- C2orf80 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 128/188 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CABS1 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 121/462 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CACNA1C | c.5467G>A p.D1823N | Missense Mutation (SNP) | VAF 174/277 reads (63%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CBY3 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 128/406 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CCDC88A | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 236/508 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CCDC88C | c.4426G>T p.G1476W | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CCT5 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD52 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 109/290 reads (38%) | called by muse, mutect2, varscan2
- CDV3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 110/489 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, varscan2
- CEP126 | c.2399C>G p.P800R | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP295 | c.225A>C p.Q75H | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP295 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHST7 | c.341C>G p.S114W | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB2 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CRACR2A | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 125/415 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CYFIP2 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CYP21A2 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 134/433 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND2C | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2
- DLEU7 | c.225G>C p.R75S | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH14 | c.10166C>G p.S3389* (on ENST00000445597; = p.S4397* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 63/263 reads (24%) | called by muse, mutect2, varscan2
- DNHD1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DST | c.20875G>C p.E6959Q (on ENST00000361203 / NM_001374722.1; = p.E4656Q on NM_015548.5) | Missense Mutation (SNP) | VAF 167/235 reads (71%) | SIFT tolerated (0.45); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DUSP9 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- DYNC2I2 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 175/513 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EMC2 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 43/437 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ENDOV | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, varscan2
- EOMES | c.1379+1G>A p.X460_splice | Splice Site (SNP) | VAF 81/171 reads (47%) | called by muse, mutect2, varscan2
- ERCC4 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- F8 | c.5027C>T p.S1676L | Missense Mutation (SNP) | VAF 140/571 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FANCF | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FGFBP2 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FKBP9 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 51/540 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2
- GDAP2 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLP1R | c.689T>G p.F230C | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GLTPD2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 173/175 reads (99%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- HELZ | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 49/336 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HFE | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HRNR | c.5687G>T p.S1896I | Missense Mutation (SNP) | VAF 184/2783 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, mutect2
- IDO1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 98/616 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IGFL3 | c.357G>C p.R119S | Missense Mutation (SNP) | VAF 180/358 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- INTS1 | c.5806C>G p.L1936V | Missense Mutation (SNP) | VAF 211/457 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRX3 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 185/600 reads (31%) | called by muse, mutect2, varscan2
- KMT2A | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 163/500 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2A | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 85/254 reads (33%) | called by muse, mutect2, varscan2
- LONRF3 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 497/678 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRC45 | c.1438_1440del p.R480del | In Frame Del (DEL) | VAF 94/200 reads (47%) | called by mutect2, pindel, varscan2
- LSM4 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 116/230 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MAS1L | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 168/575 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MEGF8 | c.3122C>G p.S1041* (on ENST00000251268 / NM_001271938.2; = p.S974* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 75/359 reads (21%) | called by muse, mutect2, varscan2
- MYO1E | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MYO5A | c.4852G>C p.E1618Q | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NDC1 | c.1788G>C p.L596F | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NDE1 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NOTCH4 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 197/640 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NRSN1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 190/314 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ONECUT3 | c.735C>G p.F245L | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR4K3 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 166/530 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5M1 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OR6N1 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 131/515 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL6 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 119/363 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PA2G4 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); called by muse, varscan2
- PAPLN | c.316T>C p.W106R | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, varscan2
- PAPLN | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHACTR4 | c.1898T>C p.V633A (on ENST00000373839 / NM_001350159.2; = p.V643A on NM_023923.4) | Missense Mutation (SNP) | VAF 137/206 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PLEKHH2 | c.4297-1G>C p.X1433_splice | Splice Site (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- POLK | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PPP1R12B | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRDM14 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 143/596 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PRKACA | c.-1_20del | Translation Start Site (DEL) | VAF 49/164 reads (30%) | called by mutect2, varscan2
- PRKCSH | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PSME4 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 114/503 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RAG1 | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 112/216 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM44 | c.668C>G p.S223C (on ENST00000611254; = p.S857C on NM_001080504.2) | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- RFX6 | c.872del p.L291Yfs*53 | Frame Shift Del (DEL) | VAF 54/189 reads (29%) | called by mutect2, pindel, varscan2
- RPE65 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- RUFY3 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SECISBP2 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SLC12A5 | c.1594C>G p.L532V (on ENST00000454036 / NM_001134771.2; = p.L509V on NM_020708.5) | Missense Mutation (SNP) | VAF 107/333 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SLC6A19 | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOX3 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 384/708 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SP100 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SP5 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 149/519 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPHKAP | c.4513G>T p.E1505* | Nonsense Mutation (SNP) | VAF 134/394 reads (34%) | called by muse, mutect2, varscan2
- SPINK1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRFBP1 | c.1034T>G p.F345C | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TBC1D23 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 173/248 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TC2N | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 135/186 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TCEANC2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TENM2 | c.2892G>T p.Q964H (on ENST00000518659 / NM_001122679.2; = p.Q732H on NM_001080428.3) | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TENM2 | c.6100G>A p.D2034N (on ENST00000518659 / NM_001122679.2; = p.D1795N on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THAP9 | c.2458C>G p.H820D | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- THUMPD3 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLK1 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLN2 | c.5497G>T p.A1833S | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS2 | c.441del p.C148Vfs*53 | Frame Shift Del (DEL) | VAF 56/392 reads (14%) | called by mutect2, pindel, varscan2
- TNIK | c.47C>G p.S16W | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- TTC37 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- UPK2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- USP45 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VRK2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 241/476 reads (51%) | called by muse, mutect2, varscan2
- YJU2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZFC3H1 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10636C>A p.P3546T | Missense Mutation (SNP) | VAF 93/827 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ZNF273 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 54/420 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZNF324 | c.1652_1653insCGGC p.E552Gfs*84 | Frame Shift Ins (INS) | VAF 65/361 reads (18%) | called by mutect2, pindel, varscan2
- ZNF439 | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZNF442 | c.1470T>G p.C490W | Missense Mutation (SNP) | VAF 131/301 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOD1 | c.1185A>C p.G395= | Silent (SNP) | VAF 96/195 reads (49%) | catalogued as rs1332565244; called by muse, mutect2, varscan2
- AF196969.1 | c.234G>A p.V78= | Silent (SNP) | VAF 136/136 reads (100%) | catalogued as CD991690; called by muse, mutect2, varscan2
- AICDA | c.186C>G p.L62= | Silent (SNP) | VAF 94/313 reads (30%) | catalogued as COSV57563546; called by muse, mutect2, varscan2
- BEST1 | c.543C>T p.F181= | Silent (SNP) | VAF 111/326 reads (34%) | catalogued as COSV57120093; called by muse, mutect2, varscan2
- BICD2 | c.561G>A p.E187= | Silent (SNP) | VAF 117/332 reads (35%) | catalogued as COSV63549714; called by muse, mutect2, varscan2
- BICRAL | c.2970C>T p.I990= | Silent (SNP) | VAF 80/250 reads (32%) | called by muse, mutect2, varscan2
- BTNL8 | c.1377C>T p.I459= | Silent (SNP) | VAF 122/392 reads (31%) | catalogued as COSV99180472; called by muse, mutect2, varscan2
- C6orf118 | c.540C>T p.P180= | Silent (SNP) | VAF 121/404 reads (30%) | catalogued as rs145574207, COSV57815725; called by muse, mutect2, varscan2
- CACNA1D | c.291G>C p.S97= | Silent (SNP) | VAF 224/224 reads (100%) | catalogued as COSV55451743; called by muse, mutect2, varscan2
- CACNA1D | c.3282C>G p.L1094= (on ENST00000350061 / NM_001128840.3; = p.L1114= on NM_000720.4) | Silent (SNP) | VAF 75/194 reads (39%) | called by muse, mutect2, varscan2
- CARD9 | c.357G>A p.L119= | Silent (SNP) | VAF 107/326 reads (33%) | called by muse, mutect2, varscan2
- CCDC80 | c.306G>A p.V102= | Silent (SNP) | VAF 36/650 reads (6%) | catalogued as COSV52816326; called by muse, mutect2
- CD22 | c.1932G>A p.L644= | Silent (SNP) | VAF 166/506 reads (33%) | called by muse, mutect2, varscan2
- CD300H | c.177A>G p.Q59= | Silent (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- CDH5 | c.2085G>A p.A695= | Silent (SNP) | VAF 211/576 reads (37%) | catalogued as rs374977157; called by muse, mutect2, varscan2
- CDK2AP2 | c.72G>T p.P24= | Silent (SNP) | VAF 85/388 reads (22%) | catalogued as rs1260361385; called by muse, mutect2, varscan2
- CERS1 | c.777C>T p.F259= | Silent (SNP) | VAF 114/222 reads (51%) | called by muse, mutect2, varscan2
- CHRNB2 | c.201C>T p.L67= | Silent (SNP) | VAF 85/308 reads (28%) | catalogued as rs773706734; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENTPD8 | c.885C>G p.A295= | Silent (SNP) | VAF 138/459 reads (30%) | called by muse, mutect2, varscan2
- ESYT1 | c.315G>A p.A105= | Silent (SNP) | VAF 89/335 reads (27%) | catalogued as rs1346157398, COSV57274810; called by muse, mutect2, varscan2
- F7 | c.117G>A p.P39= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs780290098; called by muse, mutect2, varscan2
- FZD3 | c.99G>A p.L33= | Silent (SNP) | VAF 116/116 reads (100%) | catalogued as COSV53538026, COSV99527986; called by muse, mutect2, varscan2
- GAB1 | c.1176T>C p.D392= | Silent (SNP) | VAF 55/259 reads (21%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.906G>A p.R302= | Silent (SNP) | VAF 177/465 reads (38%) | called by muse, mutect2, varscan2
- GALNTL5 | c.1119C>T p.I373= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as COSV67179152; called by muse, mutect2, varscan2
- GPR17 | c.996C>T p.F332= | Silent (SNP) | VAF 142/454 reads (31%) | called by muse, mutect2, varscan2
- H2AC11 | c.303C>T p.V101= | Silent (SNP) | VAF 139/399 reads (35%) | catalogued as rs758805616; called by muse, mutect2, varscan2
- HACD2 | c.429C>T p.I143= | Silent (SNP) | VAF 72/449 reads (16%) | called by muse, mutect2, varscan2
- HMCN1 | c.15465G>A p.R5155= | Silent (SNP) | VAF 103/419 reads (25%) | called by muse, mutect2, varscan2
- HMCN2 | c.14562C>T p.F4854= | Silent (SNP) | VAF 99/309 reads (32%) | catalogued as rs1246995787; called by muse, mutect2, varscan2
- HSPA6 | c.54G>C p.S18= | Silent (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- IFITM3 | c.324C>T p.I108= | Silent (SNP) | VAF 151/318 reads (47%) | catalogued as rs1060603; called by muse, mutect2, varscan2
- ITPR3 | c.7962G>A p.R2654= | Silent (SNP) | VAF 122/344 reads (35%) | called by muse, mutect2, varscan2
- JMJD4 | c.843C>G p.L281= | Silent (SNP) | VAF 161/710 reads (23%) | catalogued as COSV59916742; called by muse, mutect2, varscan2
- JUP | c.2145G>A p.E715= | Silent (SNP) | VAF 166/803 reads (21%) | catalogued as rs371395790; called by muse, mutect2, varscan2
- KCNF1 | c.891C>T p.I297= | Silent (SNP) | VAF 189/773 reads (24%) | catalogued as rs559871658, COSV54462612; called by muse, mutect2, varscan2
- KDM4B | c.2667C>T p.L889= | Silent (SNP) | VAF 148/298 reads (50%) | catalogued as COSV99345884; called by muse, mutect2, varscan2
- KRT34 | c.222T>C p.P74= | Silent (SNP) | VAF 252/1432 reads (18%) | catalogued as rs569964224; called by muse, mutect2, varscan2
- MALL | c.123C>G p.V41= | Silent (SNP) | VAF 139/441 reads (32%) | catalogued as COSV55600933; called by muse, mutect2, varscan2
- MICA | c.99G>A p.T33= | Silent (SNP) | VAF 144/406 reads (35%) | catalogued as rs747747009; called by muse, mutect2, varscan2
- MTREX | c.2166G>A p.E722= | Silent (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- MTUS2 | c.2091G>A p.E697= | Silent (SNP) | VAF 105/201 reads (52%) | catalogued as rs1167327375; called by muse, mutect2, varscan2
- NUSAP1 | c.717C>G p.L239= | Silent (SNP) | VAF 99/298 reads (33%) | called by muse, mutect2, varscan2
- OR3A1 | c.450G>A p.A150= | Silent (SNP) | VAF 518/519 reads (100%) | catalogued as rs779127412, COSV60163544; called by muse, mutect2, varscan2
- OR5M11 | c.543G>A p.P181= | Silent (SNP) | VAF 121/334 reads (36%) | catalogued as rs979783807, COSV73141942; called by muse, mutect2, varscan2
- OTOA | c.552G>C p.L184= | Silent (SNP) | VAF 115/305 reads (38%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1554C>T p.L518= | Silent (SNP) | VAF 246/746 reads (33%) | called by muse, varscan2
- PDE4A | c.1668G>A p.L556= (on ENST00000380702 / NM_001111307.2; = p.L317= on NM_006202.3) | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as COSV53351751; called by muse, mutect2, varscan2
- PGR | c.1935C>T p.V645= | Silent (SNP) | VAF 134/192 reads (70%) | called by muse, varscan2
- PHIP | c.4485C>T p.N1495= | Silent (SNP) | VAF 120/367 reads (33%) | catalogued as rs1474049210, COSV51502489; called by muse, mutect2, varscan2
- PIK3R4 | c.2311C>T p.L771= | Silent (SNP) | VAF 84/474 reads (18%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3859C>T p.L1287= | Silent (SNP) | VAF 152/545 reads (28%) | called by muse, mutect2, varscan2
- PIWIL4 | c.1899G>A p.V633= | Silent (SNP) | VAF 104/307 reads (34%) | catalogued as rs773701114; called by muse, mutect2, varscan2
- PNPLA2 | c.1413C>G p.P471= | Silent (SNP) | VAF 221/423 reads (52%) | catalogued as rs540018341; called by muse, mutect2, varscan2
- PNPLA7 | c.2754G>A p.A918= | Silent (SNP) | VAF 112/419 reads (27%) | catalogued as rs535218909; called by muse, mutect2, varscan2
- POLR1A | c.4677C>T p.I1559= | Silent (SNP) | VAF 116/545 reads (21%) | catalogued as rs1488385494; called by muse, mutect2, varscan2
- PTPRT | c.3546C>T p.L1182= | Silent (SNP) | VAF 74/209 reads (35%) | called by muse, mutect2, varscan2
- PXMP4 | c.594C>T p.D198= | Silent (SNP) | VAF 109/310 reads (35%) | called by muse, mutect2, varscan2
- SAGE1 | c.381C>G p.V127= | Silent (SNP) | VAF 130/511 reads (25%) | called by muse, mutect2, varscan2
- SEC16B | c.2709G>A p.G903= | Silent (SNP) | VAF 70/342 reads (20%) | called by muse, mutect2, varscan2
- SEMA6B | c.870C>G p.L290= | Silent (SNP) | VAF 153/324 reads (47%) | called by muse, mutect2, varscan2
- SLC16A1 | c.204C>G p.V68= | Silent (SNP) | VAF 76/208 reads (37%) | called by muse, varscan2
- SLC4A4 | c.334C>T p.L112= (on ENST00000264485 / NM_001098484.3; = p.L68= on NM_003759.4) | Silent (SNP) | VAF 119/484 reads (25%) | called by muse, mutect2, varscan2
- SLC6A6 | c.1302C>T p.F434= | Silent (SNP) | VAF 99/228 reads (43%) | catalogued as rs751612848; called by muse, mutect2, varscan2
- SLCO1C1 | c.1773C>T p.I591= | Silent (SNP) | VAF 62/235 reads (26%) | catalogued as COSV56875791, COSV99859852; called by muse, mutect2, varscan2
- SPTBN1 | c.414C>A p.I138= | Silent (SNP) | VAF 256/495 reads (52%) | called by muse, mutect2, varscan2
- STK19 | c.681C>G p.L227= (on ENST00000375333 / NM_032454.1; = p.L223= on NM_004197.1) | Silent (SNP) | VAF 66/203 reads (33%) | called by muse, mutect2, varscan2
- TLNRD1 | c.394C>T p.L132= | Silent (SNP) | VAF 182/493 reads (37%) | catalogued as rs747927954, COSV51256815, COSV51257583; called by muse, mutect2, varscan2
- TMCC2 | c.1326C>T p.I442= | Silent (SNP) | VAF 117/537 reads (22%) | catalogued as rs774057777; called by muse, mutect2, varscan2
- TRABD2A | c.120G>A p.L40= | Silent (SNP) | VAF 68/288 reads (24%) | called by muse, mutect2, varscan2
- TUBA4B | c.453C>T p.I151= | Silent (SNP) | VAF 145/446 reads (33%) | called by muse, mutect2, varscan2
- USP38 | c.588A>C p.T196= | Silent (SNP) | VAF 104/433 reads (24%) | called by muse, mutect2, varscan2
- WDR33 | c.297G>A p.L99= | Silent (SNP) | VAF 68/225 reads (30%) | catalogued as rs1374466993, COSV100460235; called by muse, mutect2, varscan2
- ZNRF4 | c.18G>A p.P6= | Silent (SNP) | VAF 84/180 reads (47%) | catalogued as rs369224291, COSV55773227; called by muse, mutect2, varscan2
- COL6A5 | c.*652G>C | 3'UTR (SNP) | VAF 295/372 reads (79%) | catalogued as rs1001239484; called by muse, mutect2, varscan2
- DCHS2 | n.8305C>T | RNA (SNP) | VAF 87/446 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.6924G>C | RNA (SNP) | VAF 96/423 reads (23%) | catalogued as COSV104421295; called by muse, mutect2, varscan2
- FSD2 | chr15:82750784 C>G | 3'Flank (SNP) | VAF 123/343 reads (36%) | called by muse, mutect2, varscan2
- GC | c.*60G>C | 3'UTR (SNP) | VAF 76/374 reads (20%) | called by muse, mutect2, varscan2
- HAPLN3 | c.-48+2457G>C | Intron (SNP) | VAF 108/338 reads (32%) | catalogued as rs1386576534; called by muse, mutect2
- IQCK | c.802+16C>T | Intron (SNP) | VAF 132/483 reads (27%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3100C>T | Intron (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- LDB2 | c.891+2656G>A | Intron (SNP) | VAF 78/147 reads (53%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.583G>C | RNA (SNP) | VAF 58/262 reads (22%) | catalogued as COSV59485274; called by muse, mutect2, varscan2
- SPRED3 | chr19:38388668 C>G | 5'Flank (SNP) | VAF 54/224 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.370+67C>T | Intron (SNP) | VAF 119/552 reads (22%) | called by muse, mutect2, varscan2
